Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UP, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UP-01A (Primary Tumor).

[page 1 of 3]
H/FAA Discrepancy		☒

Jeck
I Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

L PTC. Total thyroidectomy.

Specimens Submitted:

- 1: Central compartment lymph node (fs)
- 2: Left thyroid lobe (fs)
- 3: Right thyroid lobe
- 4: Left paratracheal lymph node

DIAGNOSIS:

1. Lymph node, central compartment; excision (fs):
-Two benign lymph nodes, (0/2).

2. Left thyroid lobe (fs):

Part # 2

Tumor Type:

Papillary carcinoma, follicular variant 99% pw TSS /lw

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 2.1 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

ICD-O-3

carcinoma, pap. illan, follicular variant

8340/3

Site: Thyroid, NOS

C73.9

5-2-12
RD

[page 2 of 3]
Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:

Not identified

in this part

Lymph Nodes:

Three benign lymph nodes

3. Right thyroid lobe; partial thyroidectomy:

-Chronic lymphocytic thyroiditis.

-Three benign lymph nodes, (0/3).

4. Lymph node, left paratracheal; excision:

-Sixteen benign lymph nodes, (0/16).

-Benign thymic tissue and parathyroid gland.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). Received fresh for frozen section labeled "central compartment lymph node" are two pink tan lymph nodes ranging from 0.7 to 0.8 cm in greatest dimension. They are entirely submitted in one cassette.

Summary of sections:

FSC - frozen section control

2). Received fresh for frozen section labeled "left thyroid lobe" is a 13 g 3.9 x 3.1 x 2.1 cm left lobe of thyroid with isthmus containing nodule. The posterior surface is inked black and the anterior surface inked blue. The right lobe is 3.2 x 2.5 x 2.1 cm. It contains a 2.1 x 1.9 x 1.8 cm pink-tan nodule that is well circumscribed by a thin capsule and have a pink-tan and spongy cut surface which is submitted for frozen section. Also within the lower pole is a roughly 2.5 x 2 x 1.8 ill-defined area of pink-tan discoloration that also involves the isthmus. The remaining thyroid parenchyma is pink-tan and unremarkable. It is entirely submitted for permanent sections and

Summary of sections:

FSC - frozen section control, tumor

RL - left lobe of thyroid serially sectioned from superior to inferior

IS - isthmus of thyroid serially sectioned from superior to inferior

3. The specimen is received fresh, placed in formalin, and is labeled "right thyroid lobe". It consists of a thyroid lobe measuring 4.5 x 2.2 x 1.8 cm with attached fibrous tissue measuring 3.5 x 1.0 x 0.5 cm at the mid medial aspect of the lobe. The entire specimen weigh 7.0 grams. The surface is smooth anteriorly and rugged posteriorly. The lobe is inked black posterior and blue anterior.

[page 3 of 3]
Serial sectioning reveals one white nodule that displays smooth cut surfaces. The nodule is located in the medial aspect, is not encapsulated, and measures 0.3 cm. The specimen is entirely submitted.

Summary of sections:

RT - thyroid, superior to inferior
FT- fibrous tissue

4. The specimen is received fresh and is in formalin, labeled "peritracheal lymph node", and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 1.8 cm in greatest dimension. All identified lymph nodes are submitted. The specimen is entirely submitted.

Summary of sections:

BLN - bisected lymph nodes
LN - lymph nodes

Summary of Sections:

Part 1: Central compartment lymph node (fs)

Block	Sect. Site	PCs
1	FSC	2

Part 2: Left thyroid lobe (fs)

Block	Sect. Site	PCs
1	FSC	1
2	IS	4
8	RL	8

Part 3: Right thyroid lobe

Block	Sect. Site	PCs
2	FT	4
9	RT	11

Part 4: Left paratracheal lymph node

Block	Sect. Site	PCs
3	bln	6
3	ln	9

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Central compartment lymph node (fs): Benign lymph nodes.
Permanent diagnosis: same
2. Frozen section diagnosis: Left thyroid lobe (fs): Follicular neoplasm, suspect follicular variant of papillary carcinoma. Defer.
Permanent diagnosis: see final

Source: NCI Genomic Data Commons file 44fe901a-9686-4f07-bc06-3073fa4a9b66 (TCGA-DJ-A3UP.237FE672-A255-4C6D-A53F-CF7234779BE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).